Somatic mutation profile of tumor specimen C3L-05811-54 (aliquot CPT0356770002) from CPTAC case C3L-05811, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 62.0 years (22,652 days).
Specimen C3L-05811-54: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5eef9dfe-1245-4ea1-8f36-de322b92dcc5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05811-50 (Buccal Cell Normal), aliquot CPT0356860003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb449773-d204-4aa9-8d8a-b812ebf3aad0

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, Nonsense Mutation 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.2102G>A p.R701H | Missense Mutation (SNP) | VAF 16/249 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs797044563, COSV64871348; ClinVar: likely pathogenic; called by muse, mutect2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 15/74 reads (20%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DUSP13 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 201/504 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs1052540973, COSV57816281; called by muse, mutect2, varscan2
- PHF6 | c.719A>G p.Y240C (on ENST00000332070 / NM_032458.3; = p.Y241C on NM_032335.3) | Missense Mutation (SNP) | VAF 112/303 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV59707483; called by muse, mutect2, varscan2
- SLCO6A1 | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 65/314 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV65808387, COSV65808697; called by muse, mutect2, varscan2
- TET2 | c.5541G>A p.W1847* | Nonsense Mutation (SNP) | VAF 73/151 reads (48%) | catalogued as rs918917257, COSV54399228; called by muse, mutect2, varscan2
- GGCX | c.446T>A p.V149E | Missense Mutation (SNP) | VAF 84/471 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.646A>G p.T216A | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.281); called by muse, mutect2
- ATP13A2 | c.2083C>T p.L695= | Silent (SNP) | VAF 114/300 reads (38%) | catalogued as rs757300078; called by muse, varscan2
- LASP1 | c.609C>T p.G203= | Silent (SNP) | VAF 87/197 reads (44%) | catalogued as rs1280541001, COSV58804218; called by muse, mutect2, varscan2
- PDLIM2 | c.486G>A p.P162= (on ENST00000397760; = p.P412= on NM_021630.6) | Silent (SNP) | VAF 100/260 reads (38%) | catalogued as rs755934777; called by muse, mutect2, varscan2
- TECPR2 | c.4164C>T p.H1388= | Silent (SNP) | VAF 157/353 reads (44%) | called by muse, mutect2, varscan2
- FBXW7 | c.501+29031A>G | Intron (SNP) | VAF 39/96 reads (41%) | catalogued as rs1304948339; called by muse, mutect2, varscan2
